Somatic mutation profile of tumor specimen TCGA-EJ-5514-01A (aliquot TCGA-EJ-5514-01A-01D-1576-08) from TCGA case TCGA-EJ-5514, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.2 years (24,165 days).
Specimen TCGA-EJ-5514-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 281dc3c8-55b8-4e9f-9715-d3e887c3935d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5514-10A (Blood Derived Normal), aliquot TCGA-EJ-5514-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32fa5ff5-e321-4952-a411-dc2ebd493f1e

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B1 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as COSV53811466; called by muse, mutect2
- BRINP1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148052034, COSV56309641; called by muse, mutect2, varscan2
- CACNA1E | c.5926G>A p.V1976M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as rs547396023, COSV62411589; called by mutect2, varscan2
- CACNB2 | c.1951G>A p.E651K (on ENST00000324631 / NM_201596.3; = p.E596K on NM_000724.4) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.101); catalogued as COSV56639992; called by muse, mutect2
- CCDC22 | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.911); catalogued as COSV66109539; called by muse, mutect2, varscan2
- CLSTN2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71723824; called by muse, mutect2, varscan2
- GGA3 | c.1807G>A p.D603N (on ENST00000537686 / NM_138619.4; = p.D570N on NM_014001.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373320990; called by muse, mutect2, varscan2
- GIPC3 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as CM119960, COSV59260423; called by muse, mutect2, varscan2
- IGF2BP2 | c.62A>G p.Q21R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.038); catalogued as COSV60490011; called by muse, mutect2, varscan2
- IRF2 | c.103del p.Q35Rfs*35 | Frame Shift Del (DEL) | VAF 25/86 reads (29%) | catalogued as COSV66928371; called by mutect2, pindel, varscan2
- ITK | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs202119873, COSV70064619; called by muse, mutect2, varscan2
- MMRN1 | c.3161G>C p.G1054A | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53341294; called by muse, mutect2, varscan2
- MUC17 | c.10075A>G p.T3359A | Missense Mutation (SNP) | VAF 142/615 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60299139; called by muse, mutect2, varscan2
- NPAT | c.4148G>A p.R1383H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs778117245; called by muse, varscan2
- PDS5B | c.977A>G p.H326R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.74); catalogued as COSV59732214; called by muse, mutect2, varscan2
- RIOK1 | c.1097A>G p.D366G | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV53573202; called by muse, mutect2, varscan2
- ROBO4 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs769230022, COSV60627033; called by muse, mutect2, varscan2
- S100PBP | c.5T>C p.M2T | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773425248, COSV63140454; called by muse, mutect2, varscan2
- SHOX | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as CM014908, COSV61861971; called by muse, mutect2, varscan2
- TRAF3IP2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV60676834; called by muse, mutect2, varscan2
- ZNFX1 | c.4919T>C p.L1640P | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65600671; called by muse, mutect2, varscan2
- USP31 | c.2508del p.F837Lfs*2 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- CACNG3 | c.942C>T p.P314= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs201263434, COSV50063834; called by muse, mutect2, varscan2
- CMYA5 | c.1593C>T p.I531= | Silent (SNP) | VAF 84/243 reads (35%) | catalogued as rs988006197, COSV71408605; called by muse, mutect2, varscan2
- GANC | c.864G>A p.S288= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs369762885; called by muse, mutect2, varscan2
- LEXM | c.975C>T p.P325= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as rs200876449, COSV64023812; called by muse, mutect2, varscan2
- PNLIPRP1 | c.600C>T p.F200= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs113515929; called by muse, mutect2, varscan2
- SAFB2 | c.1716C>T p.V572= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs149716077, COSV53044489; called by muse, mutect2, varscan2
- SLC25A13 | c.1827T>C p.I609= | Silent (SNP) | VAF 90/360 reads (25%) | catalogued as COSV55711934; called by muse, mutect2, varscan2
- VCAN | c.882C>T p.C294= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs751444743, COSV54113470; called by muse, mutect2
- WDR43 | c.1074T>G p.T358= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56099610; called by muse, varscan2
- ZBED1 | c.825C>T p.I275= | Silent (SNP) | VAF 81/295 reads (27%) | catalogued as rs776679539, COSV58129861; called by muse, mutect2, varscan2
- OSGIN1 | n.1305T>C | RNA (SNP) | VAF 26/106 reads (25%) | catalogued as COSV59422660; called by muse, mutect2, varscan2
